Somatic mutation profile of tumor specimen 0DVCFK from CCDI case PBCMKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 2.6 years (934 days).
Specimen 0DVCFK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73e0b2e5-01c9-499f-8e0f-f6e66f7d947e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f444860e-7b77-4287-bdb9-d3edc966db3b

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'UTR 1, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BSN | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755425111, COSV56517125; called by muse, mutect2, varscan2
- CCDC17 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs946346757; called by muse, mutect2, varscan2
- CCDC88C | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as rs1064794398, COSV66238725, COSV66239297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGAP6 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755472720; called by muse, mutect2, varscan2
- SLC16A2 | c.180C>G p.D60E | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV52083887; called by muse, mutect2, varscan2
- DOHH | c.276G>T p.G92= | Splice Region (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- POU2F1 | c.1509C>G p.N503K (on ENST00000541643 / NM_001365848.1; = p.N526K on NM_002697.4) | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PSG7 | c.609C>A p.Y203* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- INTS6L | c.1224A>C p.P408= | Silent (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- PTPRS | c.3666C>T p.P1222= | Silent (SNP) | VAF 51/268 reads (19%) | catalogued as rs368871496; called by muse, mutect2, varscan2
- APEH | c.2094-15G>C | Intron (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- ATOH8 | c.*72C>T | 3'UTR (SNP) | VAF 55/133 reads (41%) | catalogued as rs938524517; called by muse, mutect2, varscan2
